Somatic mutation profile of tumor specimen TARGET-20-PASCGC-03A (aliquot TARGET-20-PASCGC-03A-01D) from TARGET case TARGET-20-PASCGC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,255 days).
Specimen TARGET-20-PASCGC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e0afd58-f503-4491-89e4-a878b3e4e2ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASCGC-10A (Blood Derived Normal), aliquot TARGET-20-PASCGC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f21eb3d5-1616-403d-94b4-5859960a6973

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 127/429 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AK9 | c.2097_2100del p.E700Kfs*12 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs776656230; called by pindel, varscan2
- GRIK2 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100024396, COSV59710691; called by muse, mutect2, varscan2
- WT1 | c.1106C>A p.S369* | Nonsense Mutation (SNP) | VAF 50/194 reads (26%) | catalogued as CM971595, COSV60065297; called by muse, mutect2, varscan2
- SULT6B1 | c.141G>A p.A47= (on ENST00000535679 / NM_001367551.1; = p.A9= on NM_001032377.2) | Silent (SNP) | VAF 24/492 reads (5%) | catalogued as rs778510865, COSV99573394; called by muse, mutect2
